Somatic mutation profile of tumor specimen 0DCZR8 from CCDI case PBBNCV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Large cell medulloblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.9 years (1,077 days).
Specimen 0DCZR8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a86239c-418c-41d7-a375-2111160b9de2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCZR9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e210b2d-8c81-4f71-8b4e-20af73b1d35f

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2C1 | c.2198A>G p.Q733R | Missense Mutation (SNP) | VAF 23/844 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM117857; called by muse, mutect2
- FAT1 | c.10285G>A p.D3429N | Missense Mutation (SNP) | VAF 286/631 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs747735486, COSV71671990; called by muse, mutect2, varscan2
- KDM6A | c.2702G>T p.R901M | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100938522, COSV65037143, COSV65039959; called by muse, mutect2
- OR4K5 | c.604A>C p.N202H | Missense Mutation (SNP) | VAF 66/736 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs748052234; called by muse, mutect2
- PLOD2 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 74/790 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1468900521; called by muse, mutect2
- PLEKHH2 | c.2402C>T p.A801V | Missense Mutation (SNP) | VAF 42/1208 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2
- TMEM185B | c.179T>G p.V60G | Missense Mutation (SNP) | VAF 48/810 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- RASAL3 | c.690G>A p.E230= | Silent (SNP) | VAF 68/931 reads (7%) | catalogued as COSV59139380, COSV59139970; called by muse, mutect2
- IMPA1 | c.*89T>A | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- TBX1 | c.*35C>T | 3'UTR (SNP) | VAF 225/464 reads (48%) | catalogued as rs765951294, COSV61549423; called by muse, mutect2, varscan2
